Surgical pathology report (de-identified scan), TCGA case TCGA-06-0213, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0213-01A (Primary Tumor).

[page 1 of 2]
PATH.NO:

TCGA-06-0213

PATHOLOGICAL DIAGNOSIS:

A,B. BRAIN, LEFT PARIETAL LOBE, EXCISION: GLIOBLASTOMA MULTIFORME.

ADDENDUM DIAGNOSIS: A,B. BRAIN, LEFT PARIETAL LOBE, EXCISION:
GLIOBLASTOMA MULTIFORME. MIB-1 LABELLING INDEX: 20 PERCENT.

Operation/Specimen: Brain tumor - [REDACTED]

Clinical History and Pre-Op Dx: Brain tumor= two month h/o progressive speech difficulty and loss of recent memory.

GROSS PATHOLOGY:

A.

SPECIMEN: Brain tumor, [REDACTED]
FIXATIVE: None.
GENERAL: Three hemorrhagic and necrotic fragments 1.6 x 0.7 x 0.4 cm. aggregate.
INTRAOPERATIVE CONSULTATION, Frozen section diagnosis: Glioma, necrotizing. [REDACTED]
SECTIONS: IFS - remnant, 2, 3 - remaining entirely.

B.

SPECIMEN: Parietal tumor.
FIXATIVE: Formalin.
GENERAL: Irregular necrotic grain tissue, 1.8 x 1.2 x 0.6 cm.
SECTIONS: Entirely submitted in 4-6.
[REDACTED]

MICROSCOPIC: A,B. Frozen section diagnosis is confirmed. Sections show a glioblastoma multiforme with large areas of coagulative necrosis and thrombosed vessels. This is a proliferation of multinucleated monstrous cells with bizarre nuclei and atypical mitoses. Occasional areas of vascular proliferation are present.

COMMENT: Labelling index (MIB-1) will be done and reported later.

[page 2 of 2]
TCGA-06-0213

Source: NCI Genomic Data Commons file 22e811a2-cede-4ad2-817a-f9b930dda46c (TCGA-06-0213.CD4F16DD-EB6A-40E3-82E7-07F878975E3B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).